Somatic mutation profile of tumor specimen 0DX7FU from CCDI case PBCRBC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.6 years (236 days).
Specimen 0DX7FU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb491847-924d-433b-80bd-07d3328be569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b049326a-862a-40e4-97ce-5d3a0bdf0e39

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM28 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 63/979 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738720; called by muse, mutect2
- HAO1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 49/1244 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs138358725; called by muse, mutect2
- SPG11 | c.3291G>C p.Q1097H | Missense Mutation (SNP) | VAF 72/1632 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
